Somatic mutation profile of tumor specimen TARGET-10-PAPIJD-09A (aliquot TARGET-10-PAPIJD-09A-01D) from TARGET case TARGET-10-PAPIJD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,226 days).
Specimen TARGET-10-PAPIJD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 021dfece-17a0-4a49-924c-493e8a09140e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPIJD-14A (Bone Marrow Normal), aliquot TARGET-10-PAPIJD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2836e974-93e8-47b6-865f-5644fa24222e

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, In Frame Ins 1, 5'Flank 1, Silent 1, Nonsense Mutation 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2
- BIRC3 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54815503; called by muse, mutect2, varscan2
- DUSP16 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs775499226, COSV53806349; called by muse, mutect2, varscan2
- ETV6 | c.1058G>C p.R353P | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1511694, COSV56766649; called by mutect2, varscan2
- KRAS | c.349A>T p.K117* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV55716212; called by muse, mutect2
- TSNARE1 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777319336, COSV56177401; called by muse, mutect2, varscan2
- CCDC149 | c.1177G>T p.A393S (on ENST00000635206 / NM_001330643.2; = p.A382S on NM_173463.5) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SELENOO | c.1385G>A p.S462N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- XPO1 | c.1152_1153insAATGAC p.S384_P385insND | In Frame Ins (INS) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- TMOD1 | c.13C>A p.R5= | Silent (SNP) | VAF 11/117 reads (9%) | called by muse, mutect2, varscan2
- AL033384.1 | chr6:53930027 C>T | 5'Flank (SNP) | VAF 6/19 reads (32%) | catalogued as rs1482340714; called by muse, mutect2
- RARRES2P6 | n.154G>A | RNA (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- ZNF233 | c.-8A>G | 5'UTR (SNP) | VAF 35/66 reads (53%) | catalogued as rs758017257; called by muse, mutect2, varscan2
